Somatic mutation profile of tumor specimen HCM-SANG-0271-D12-86A (aliquot HCM-SANG-0271-D12-86A-01D-A85C-36) from HCMI case HCM-SANG-0271-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Tubular adenoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: GX.
Specimen HCM-SANG-0271-D12-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 225bdac6-af9c-449e-8154-6544b5a23891.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0271-D12-10A (Blood Derived Normal), aliquot HCM-SANG-0271-D12-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cdc3e1c-6b8c-4f66-8146-06e0e836b86b

The open-access MAF lists 221 somatic variants for this specimen: 157 protein-altering or splice-affecting, 56 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 56, Nonsense Mutation 11, Intron 5, Splice Site 3, In Frame Del 2, Frame Shift Del 2, Splice Region 2, 5'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3186_3187del p.S1063* | Frame Shift Del (DEL) | VAF 133/256 reads (52%) | catalogued as rs1060503362; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 186/381 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 209/466 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782620, CM132087, COSV52665025, COSV53025766, COSV53135444, COSV53176166; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- AADACL3 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60198602; called by muse, mutect2
- ADAMTS13 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 243/560 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs782511560; called by muse, mutect2, varscan2
- ADCY9 | c.3518C>T p.T1173M | Missense Mutation (SNP) | VAF 266/548 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1371707087, COSV53572532; called by muse, mutect2
- AKIRIN1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs1315318370; called by muse, mutect2, varscan2
- ALK | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 140/524 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs745499366, COSV66577674; ClinVar: uncertain significance; called by muse, varscan2
- ATP13A5 | c.2705C>T p.S902F | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1393318983; called by muse, mutect2, varscan2
- B3GALT5 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1454210645; called by muse, mutect2, varscan2
- BIRC6 | c.13730G>A p.R4577H | Missense Mutation (SNP) | VAF 370/577 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101428256; called by muse, mutect2, varscan2
- CCN5 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 82/2445 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778811911; called by muse, mutect2
- COL12A1 | c.4795C>T p.R1599* | Nonsense Mutation (SNP) | VAF 59/337 reads (18%) | catalogued as COSV100485159, COSV59401096; called by muse, mutect2, varscan2
- CSMD3 | c.7032C>G p.D2344E (on ENST00000297405 / NM_001363185.1; = p.D2240E on NM_052900.3) | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV52334770; called by muse, mutect2, varscan2
- CXCR4 | c.82T>A p.C28S | Missense Mutation (SNP) | VAF 157/434 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54009986; called by muse, mutect2, varscan2
- DACT1 | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 69/598 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.29); catalogued as rs764224780; called by muse, mutect2, varscan2
- DCDC1 | c.3394C>A p.L1132I (on ENST00000597505 / NM_001367979.1; = p.L239I on NM_020869.3) | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.178); catalogued as COSV60305246, COSV60308419; called by muse, mutect2, varscan2
- DOK7 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 419/420 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs769289951; called by muse, mutect2, varscan2
- ENPP7 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 55/498 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs782158669, COSV60386876; called by muse, mutect2, varscan2
- EPHA3 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs773476878, COSV60719749; called by muse, mutect2, varscan2
- ERICH4 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 241/392 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs782111142; called by muse, mutect2, varscan2
- ERVMER34-1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 163/398 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs1051087038; called by muse, mutect2, varscan2
- F8 | c.4106G>A p.S1369N | Missense Mutation (SNP) | VAF 60/603 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs367892017; called by muse, mutect2
- FAM110A | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 280/1004 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs957098379; called by muse, mutect2, varscan2
- FOSB | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1180159338; called by muse, mutect2
- FRG2B | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as rs754809295; called by mutect2, varscan2
- H2BC11 | c.94C>G p.R32G | Missense Mutation (SNP) | VAF 61/376 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs769130601; called by muse, mutect2, varscan2
- HECTD1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 302/302 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1200713364, COSV67947686; called by muse, mutect2, varscan2
- HK3 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 226/353 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771626485, COSV52842984; called by muse, mutect2, varscan2
- IGSF10 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 170/326 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs374510873, COSV99193968; called by muse, varscan2
- IKZF4 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 61/771 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs370401917; called by muse, mutect2
- KCNB2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 94/445 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV73050947, COSV73053233; called by muse, mutect2, varscan2
- KCNMA1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54237087, COSV54243900; called by muse, mutect2, varscan2
- KIF19 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 127/392 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs765728283, COSV63428708; called by muse, mutect2, varscan2
- KRR1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 183/417 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs549769836, COSV56991708; called by muse, mutect2, varscan2
- KRT23 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 286/540 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs750245687, COSV52926972, COSV52929212; called by muse, mutect2, varscan2
- LZTR1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 167/349 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs970027059, COSV99301246; called by muse, mutect2, varscan2
- MAGEA12 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 112/462 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs1556833500, COSV100757013, COSV63295146; called by muse, varscan2
- MAGEB10 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 220/473 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as rs754281513; called by muse, mutect2, varscan2
- MAGEB6B | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1046848646; called by muse, mutect2, varscan2
- MBNL2 | c.727A>C p.K243Q | Missense Mutation (SNP) | VAF 401/834 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.501); catalogued as COSV59117309; called by muse, mutect2, varscan2
- MINAR1 | c.2299-1G>C p.X767_splice | Splice Site (SNP) | VAF 62/282 reads (22%) | catalogued as COSV59586069; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 58/848 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.745); catalogued as rs760012733; called by muse, mutect2
- MYH14 | c.2975C>T p.T992M | Missense Mutation (SNP) | VAF 320/503 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs201746408, COSV51826998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.4402G>C p.E1468Q | Missense Mutation (SNP) | VAF 138/416 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs755024942; called by muse, mutect2, varscan2
- NBR1 | c.244G>C p.V82L | Missense Mutation (SNP) | VAF 141/293 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV57835849; called by muse, mutect2, varscan2
- NUDT4 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV100455689; called by muse, varscan2
- OCSTAMP | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 275/1850 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs868469717, COSV99645009; called by muse, mutect2, varscan2
- OSMR | c.411A>C p.E137D | Missense Mutation (SNP) | VAF 21/327 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV99952532; called by muse, mutect2
- OTOG | c.8321C>A p.S2774Y | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs1042461886; called by muse, mutect2
- PLXNA2 | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 108/609 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs771610537, COSV65439741; called by muse, mutect2, varscan2
- PTPRS | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 244/585 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs1224185745; called by muse, mutect2, varscan2
- RRAGC | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 149/149 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs761415462, COSV65931302; called by muse, mutect2, varscan2
- RYR2 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs1283158734; called by muse, mutect2, varscan2
- SIX6 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 271/558 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs886050563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO3A1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 331/679 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV59229085; called by muse, mutect2, varscan2
- SSH3 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 178/421 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200078645; called by muse, mutect2, varscan2
- SUFU | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 215/386 reads (56%) | catalogued as COSV64014466; called by muse, mutect2, varscan2
- TCF4 | c.525A>C p.K175N | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV61891740; called by muse, mutect2, varscan2
- TDRD9 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 299/299 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs781139035; called by muse, mutect2, varscan2
- TNFRSF11A | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 134/470 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1020903615, COSV54022728; called by muse, mutect2, varscan2
- TPO | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 423/1181 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs1173922703; called by muse, mutect2
- TTN | c.4871A>T p.D1624V (on ENST00000591111; = p.D1578V on NM_003319.4) | Missense Mutation (SNP) | VAF 31/546 reads (6%) | PolyPhen probably damaging (0.999); catalogued as rs1290278898; called by muse, mutect2
- URGCP | c.682C>A p.L228M (on ENST00000453200 / NM_001077663.3; = p.L219M on NM_017920.4) | Missense Mutation (SNP) | VAF 91/737 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.64); catalogued as COSV56250117; called by muse, mutect2, varscan2
- ZC3H12C | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 159/389 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1256899304; called by muse, mutect2, varscan2
- ZFPM2 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 278/490 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770304470; called by muse, mutect2, varscan2
- ZNF614 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs778179613; called by muse, mutect2, varscan2
- ZNF831 | c.610T>A p.S204T | Missense Mutation (SNP) | VAF 50/1624 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.477); catalogued as COSV64039254; called by muse, mutect2
- AASS | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 167/675 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- AATK | c.2415G>C p.E805D (on ENST00000326724 / NM_001080395.3; = p.E702D on NM_004920.2) | Missense Mutation (SNP) | VAF 299/552 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACVR1C | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 97/516 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTSL3 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 76/331 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ADARB2 | c.1683-8C>A | Splice Region (SNP) | VAF 468/468 reads (100%) | called by muse, mutect2, varscan2
- AL592490.1 | c.1578A>C p.L526F | Missense Mutation (SNP) | VAF 64/434 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- APOB | c.1622A>T p.Q541L | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ARHGAP24 | c.440A>C p.Y147S (on ENST00000395184 / NM_001025616.3; = p.Y54S on NM_031305.3) | Missense Mutation (SNP) | VAF 64/360 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ARHGEF38 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 50/470 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- ASCC3 | c.817G>T p.G273* | Nonsense Mutation (SNP) | VAF 23/291 reads (8%) | called by muse, mutect2
- ATP4A | c.980C>A p.T327N | Missense Mutation (SNP) | VAF 50/750 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.109); called by muse, mutect2
- BRWD3 | c.2961G>T p.K987N | Missense Mutation (SNP) | VAF 131/260 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC168 | c.8731C>T p.Q2911* | Nonsense Mutation (SNP) | VAF 115/507 reads (23%) | called by muse, mutect2, varscan2
- CCDC178 | c.1480C>T p.H494Y | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHD4 | c.5083_5086+1dup p.X1695_splice (on ENST00000357008 / NM_001363606.2; = p.X1706_splice on NM_001273.5) | Splice Site (INS) | VAF 161/264 reads (61%) | called by mutect2, pindel, varscan2
- CLEC5A | c.46A>C p.K16Q | Missense Mutation (SNP) | VAF 177/565 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CNNM1 | c.544A>C p.K182Q | Missense Mutation (SNP) | VAF 187/488 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- COX7A2 | c.176A>T p.K59I | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CYTH4 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DGKI | c.1689C>A p.F563L | Missense Mutation (SNP) | VAF 62/497 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2
- DOK5 | c.236C>G p.A79G | Missense Mutation (SNP) | VAF 147/1273 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- FSIP2 | c.19515A>T p.Q6505H | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.195); called by muse, mutect2
- GBP7 | c.1528A>T p.K510* | Nonsense Mutation (SNP) | VAF 149/360 reads (41%) | called by muse, mutect2, varscan2
- GLYATL2 | c.355A>C p.T119P | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.105); called by muse, mutect2
- GPI | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 216/650 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2AC12 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- HSP90AA1 | c.449_450del p.V150Dfs*5 | Frame Shift Del (DEL) | VAF 135/411 reads (33%) | called by pindel, varscan2
- IRS2 | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 54/1088 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JAK3 | c.984_984+7del p.X328_splice | Splice Site (DEL) | VAF 28/266 reads (11%) | called by mutect2, pindel, varscan2
- KANK2 | c.1194C>A p.N398K | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KANK3 | c.809A>C p.D270A | Missense Mutation (SNP) | VAF 17/654 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.039); called by muse, mutect2
- KCND1 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 338/680 reads (50%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCTD9 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- LARGE1 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRMDA | c.26C>A p.T9N | Missense Mutation (SNP) | VAF 28/503 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, mutect2
- LRRC9 | c.2311C>T p.Q771* | Nonsense Mutation (SNP) | VAF 94/426 reads (22%) | called by muse, mutect2, varscan2
- LY6H | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 41/423 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LYZL1 | c.285C>A p.C95* (on ENST00000375500; = p.C49* on NM_032517.6) | Nonsense Mutation (SNP) | VAF 154/399 reads (39%) | called by muse, mutect2, varscan2
- MACF1 | c.19040G>T p.R6347I (on ENST00000372915; = p.R4392I on NM_012090.5) | Missense Mutation (SNP) | VAF 65/276 reads (24%) | called by muse, mutect2, varscan2
- MBD5 | c.4190C>A p.T1397N | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MCUB | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, mutect2
- MLLT10 | c.3128C>T p.T1043I (on ENST00000307729 / NM_001195626.3; = p.P1018S on NM_004641.3) | Missense Mutation (SNP) | VAF 22/842 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2
- MMP17 | c.1363G>C p.D455H | Missense Mutation (SNP) | VAF 65/787 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- MMRN2 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 84/570 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MRPL38 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 102/585 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MRRF | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 85/120 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MYCBP2 | c.12362G>C p.S4121T (on ENST00000357337; = p.S4159T on NM_015057.5) | Missense Mutation (SNP) | VAF 65/435 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MYOM1 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 51/743 reads (7%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.091); called by muse, mutect2
- NOCT | c.176C>G p.S59W | Missense Mutation (SNP) | VAF 55/495 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.186); called by muse, mutect2
- ODC1 | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 46/620 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.11); called by muse, mutect2
- OR10A6 | c.834C>G p.Y278* | Nonsense Mutation (SNP) | VAF 24/462 reads (5%) | called by muse, mutect2
- OR5L2 | c.615G>C p.L205F | Missense Mutation (SNP) | VAF 175/404 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OXSM | c.1271A>T p.Y424F | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PANX1 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2
- PCDHA1 | c.2236G>T p.G746W | Missense Mutation (SNP) | VAF 118/360 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCLO | c.15302C>A p.S5101Y | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCMTD1 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 102/258 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PIKFYVE | c.1648T>A p.S550T | Missense Mutation (SNP) | VAF 133/343 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PKM | c.806G>T p.S269I | Missense Mutation (SNP) | VAF 155/343 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PRAME | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 178/380 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- PRR29 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 94/505 reads (19%) | called by muse, mutect2, varscan2
- RASGRP3 | c.1362_1364del p.F454del (on ENST00000402538 / NM_001349975.2; = p.F453del on NM_015376.2 and 4 other RefSeq transcripts) | In Frame Del (DEL) | VAF 60/341 reads (18%) | called by pindel, varscan2
- RASSF10 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 234/575 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM46 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF6 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 73/519 reads (14%) | called by muse, mutect2, varscan2
- SASH1 | c.2208C>A p.N736K | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SLAIN1 | c.1405T>C p.S469P (on ENST00000466548; = p.S206P on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/588 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC16A9 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- SYNGR2 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 139/815 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TAPBP | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 201/536 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TBC1D5 | c.1142T>A p.I381N | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TEX55 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- TP53I11 | c.180G>C p.L60F | Missense Mutation (SNP) | VAF 189/360 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); called by muse, mutect2
- TRPV1 | c.1044G>A p.G348= | Splice Region (SNP) | VAF 139/251 reads (55%) | called by muse, mutect2, varscan2
- TSC22D2 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- USH2A | c.11119A>C p.K3707Q | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- VCAM1 | c.1640G>C p.S547T | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); called by muse, mutect2
- VCAN | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- VEGFD | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 96/433 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- VPS41 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- WDR75 | c.1984_1986del p.S662del | In Frame Del (DEL) | VAF 121/239 reads (51%) | called by mutect2, pindel, varscan2
- XPO1 | c.2554C>T p.L852F | Missense Mutation (SNP) | VAF 42/490 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZBTB1 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 403/403 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ZC3H11A | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 99/385 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF284 | c.1443A>C p.K481N | Missense Mutation (SNP) | VAF 128/350 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF32 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- ZNF607 | c.1893_1900del p.Y631* | Nonsense Mutation (DEL) | VAF 79/511 reads (15%) | called by mutect2, pindel, varscan2
- ZNF844 | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 136/260 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, varscan2
- ZW10 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.076); called by muse, mutect2
- ADAMTS2 | c.2109C>T p.I703= | Silent (SNP) | VAF 110/185 reads (59%) | catalogued as rs200210415, COSV52375142; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- ADD2 | c.45G>A p.P15= | Silent (SNP) | VAF 232/689 reads (34%) | catalogued as COSV52469298; called by muse, mutect2, varscan2
- AK9 | c.2478C>T p.P826= | Silent (SNP) | VAF 213/280 reads (76%) | catalogued as rs958543521, COSV58139097, COSV58140680; called by muse, varscan2
- BSN | c.4665C>A p.P1555= | Silent (SNP) | VAF 36/402 reads (9%) | called by muse, mutect2
- CCDC183 | c.642C>A p.A214= | Silent (SNP) | VAF 29/239 reads (12%) | called by muse, mutect2, varscan2
- CCDC186 | c.1680G>A p.L560= | Silent (SNP) | VAF 79/132 reads (60%) | called by muse, mutect2, varscan2
- CHST10 | c.270C>T p.N90= | Silent (SNP) | VAF 157/441 reads (36%) | catalogued as rs148626049, COSV99958968; called by muse, mutect2, varscan2
- CNTN6 | c.921T>A p.L307= | Silent (SNP) | VAF 30/224 reads (13%) | called by muse, mutect2, varscan2
- COL15A1 | c.3667C>T p.L1223= | Silent (SNP) | VAF 26/252 reads (10%) | catalogued as COSV66641079; called by muse, mutect2, varscan2
- CSMD1 | c.4767C>T p.Y1589= (on ENST00000520002; = p.Y1588= on NM_033225.6) | Silent (SNP) | VAF 135/323 reads (42%) | catalogued as rs1258606725; called by muse, mutect2, varscan2
- DDI1 | c.1065C>T p.G355= | Silent (SNP) | VAF 22/489 reads (4%) | called by muse, mutect2
- DLX5 | c.696G>T p.S232= | Silent (SNP) | VAF 316/1028 reads (31%) | called by muse, mutect2, varscan2
- ELP2 | c.174C>T p.T58= | Silent (SNP) | VAF 50/282 reads (18%) | catalogued as rs150889303, COSV52369120; called by muse, mutect2, varscan2
- FCRL4 | c.750C>T p.T250= | Silent (SNP) | VAF 388/388 reads (100%) | catalogued as rs775384031, COSV99619138; called by muse, mutect2, varscan2
- FIGN | c.1074C>T p.N358= | Silent (SNP) | VAF 160/693 reads (23%) | called by muse, mutect2, varscan2
- GDF6 | c.1014C>T p.F338= | Silent (SNP) | VAF 94/482 reads (20%) | catalogued as rs1474559057, COSV99747493; called by muse, mutect2, varscan2
- GGH | c.783A>T p.A261= | Silent (SNP) | VAF 69/438 reads (16%) | called by muse, mutect2, varscan2
- GOLM2 | c.96C>T p.Y32= | Silent (SNP) | VAF 294/601 reads (49%) | called by muse, mutect2, varscan2
- GPR132 | c.201G>A p.A67= | Silent (SNP) | VAF 617/618 reads (100%) | catalogued as rs575453416, COSV61677884; called by muse, mutect2, varscan2
- GPR32 | c.234C>A p.T78= | Silent (SNP) | VAF 234/692 reads (34%) | catalogued as rs771826086; called by muse, mutect2, varscan2
- HECTD4 | c.4401G>A p.T1467= | Silent (SNP) | VAF 200/421 reads (48%) | catalogued as rs533197509, COSV61180963; called by muse, mutect2, varscan2
- IFIT1 | c.552T>C p.S184= | Silent (SNP) | VAF 244/244 reads (100%) | called by muse, mutect2, varscan2
- KBTBD13 | c.969C>T p.Y323= | Silent (SNP) | VAF 258/548 reads (47%) | catalogued as rs568613948, COSV71351377; called by muse, mutect2, varscan2
- KCNMB1 | c.159C>T p.C53= | Silent (SNP) | VAF 47/188 reads (25%) | called by muse, mutect2, varscan2
- KLHL34 | c.147C>T p.C49= | Silent (SNP) | VAF 30/610 reads (5%) | called by muse, mutect2
- MAD1L1 | c.1080G>T p.R360= | Silent (SNP) | VAF 50/715 reads (7%) | called by muse, mutect2
- MAST1 | c.1182C>T p.R394= | Silent (SNP) | VAF 155/278 reads (56%) | catalogued as rs778656447, COSV52248363; called by muse, mutect2, varscan2
- MYH13 | c.1902C>G p.S634= | Silent (SNP) | VAF 105/217 reads (48%) | called by muse, mutect2, varscan2
- NACAD | c.3816G>A p.P1272= | Silent (SNP) | VAF 185/763 reads (24%) | catalogued as rs888779393, COSV101512091; called by muse, mutect2, varscan2
- NAT10 | c.2109C>T p.A703= | Silent (SNP) | VAF 161/373 reads (43%) | catalogued as rs779738249; called by muse, mutect2, varscan2
- NRIP1 | c.1029T>C p.A343= | Silent (SNP) | VAF 68/247 reads (28%) | called by muse, mutect2, varscan2
- NWD1 | c.453G>A p.L151= | Silent (SNP) | VAF 14/404 reads (3%) | called by muse, mutect2
- NXF3 | c.861G>A p.T287= | Silent (SNP) | VAF 197/395 reads (50%) | catalogued as rs201477119, COSV67702814; called by muse, mutect2, varscan2
- OR2H1 | c.261G>A p.K87= | Silent (SNP) | VAF 298/706 reads (42%) | called by muse, mutect2, varscan2
- OR6X1 | c.585C>A p.L195= | Silent (SNP) | VAF 10/296 reads (3%) | called by muse, mutect2
- PDP1 | c.546C>T p.S182= | Silent (SNP) | VAF 200/489 reads (41%) | catalogued as rs202034256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITX1 | c.486G>A p.P162= | Silent (SNP) | VAF 103/353 reads (29%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4030C>A p.R1344= | Silent (SNP) | VAF 38/445 reads (9%) | catalogued as rs375720148; called by muse, mutect2
- POLR2H | c.102T>A p.S34= | Silent (SNP) | VAF 90/243 reads (37%) | called by muse, mutect2, varscan2
- PTPRT | c.1290C>T p.F430= | Silent (SNP) | VAF 193/1378 reads (14%) | called by muse, mutect2, varscan2
- RNF133 | c.351A>G p.K117= | Silent (SNP) | VAF 221/529 reads (42%) | called by muse, mutect2, varscan2
- RNF213 | c.14901C>A p.G4967= | Silent (SNP) | VAF 73/412 reads (18%) | catalogued as rs775932728; called by muse, mutect2, varscan2
- SDHA | c.117G>C p.G39= | Silent (SNP) | VAF 52/380 reads (14%) | catalogued as CD137030, COSV99371562; called by muse, mutect2, varscan2
- SFRP2 | c.283C>T p.L95= | Silent (SNP) | VAF 44/734 reads (6%) | called by muse, mutect2
- SKOR2 | c.699C>T p.A233= | Silent (SNP) | VAF 94/435 reads (22%) | called by muse, mutect2, varscan2
- SLC12A5 | c.270C>T p.N90= (on ENST00000454036 / NM_001134771.2; = p.N67= on NM_020708.5) | Silent (SNP) | VAF 54/1514 reads (4%) | called by muse, mutect2
- SLC15A3 | c.1626C>T p.F542= | Silent (SNP) | VAF 36/472 reads (8%) | called by muse, mutect2
- SSTR4 | c.297C>T p.S99= | Silent (SNP) | VAF 77/958 reads (8%) | catalogued as COSV54797126; called by muse, mutect2
- TEX37 | c.111G>A p.T37= | Silent (SNP) | VAF 49/374 reads (13%) | catalogued as rs370424706; called by muse, mutect2, varscan2
- TRIM23 | c.1659A>T p.G553= | Silent (SNP) | VAF 107/283 reads (38%) | called by muse, mutect2, varscan2
- UBASH3B | c.447C>T p.T149= | Silent (SNP) | VAF 204/478 reads (43%) | catalogued as rs1211610353; called by muse, mutect2, varscan2
- USP42 | c.3381G>A p.P1127= | Silent (SNP) | VAF 74/1200 reads (6%) | catalogued as rs1263106653; called by muse, mutect2
- ZIC1 | c.1026C>G p.R342= | Silent (SNP) | VAF 101/237 reads (43%) | called by muse, mutect2, varscan2
- ZNF175 | c.1827C>T p.H609= | Silent (SNP) | VAF 82/480 reads (17%) | catalogued as rs1455422704; called by muse, mutect2, varscan2
- ZNF564 | c.1599C>T p.Y533= | Silent (SNP) | VAF 20/251 reads (8%) | catalogued as rs376997794; called by muse, mutect2
- ZNF71 | c.414C>G p.A138= | Silent (SNP) | VAF 89/519 reads (17%) | called by muse, mutect2, varscan2
- ADAP1 | chr7:955399 C>G | 5'Flank (SNP) | VAF 47/366 reads (13%) | called by muse, mutect2, varscan2
- DAPK2 | c.858+1789T>C | Intron (SNP) | VAF 129/265 reads (49%) | called by muse, mutect2, varscan2
- DNAH9 | c.904+32T>C | Intron (SNP) | VAF 203/411 reads (49%) | catalogued as rs774772560; called by muse, mutect2, varscan2
- KIR3DX1 | n.29G>C | RNA (SNP) | VAF 134/512 reads (26%) | catalogued as rs535648212, COSV55601555; called by muse, mutect2, varscan2
- KPNA4 | c.-227C>T | 5'UTR (SNP) | VAF 39/293 reads (13%) | catalogued as rs1052285159; called by muse, mutect2, varscan2
- NUDT7 | c.190-326G>A | Intron (SNP) | VAF 96/210 reads (46%) | catalogued as rs965893001; called by muse, mutect2, varscan2
- TTN | c.10360+5310A>C | Intron (SNP) | VAF 40/402 reads (10%) | catalogued as COSV59888409; called by muse, mutect2
- ZNF665 | c.-54+10428G>C | Intron (SNP) | VAF 92/392 reads (23%) | called by muse, mutect2, varscan2
